Surgical pathology report (de-identified scan), TCGA case TCGA-50-5931, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-5931-01A (Primary Tumor).

[page 1 of 2]
Addendum

Fluorescent in-situ hybridization studies have been performed on the adenocarcinoma. The ratio of Her2/Neu gene to the centromere of chromosome 17 is 2.19, indicating amplification. The ratio of cyclin D1 gene to the centromere of chromosome 11 is 2.10, also indicating amplification in the targeted region. The ratio of EGFR gene to the centromere of chromosome 7 is 1.03, indicating a lack of amplification in this area.

Her2/neu and Cyclin D1 amplification may help in identifying those patients likely to experience shorter survival when considered together with other major risk factors.

Addendum

Special stains were ordered for chromogranin, synaptophysin, and mucin to further characterize the tumor and to rule out the possibility of a neuroendocrine origin for the tumor.

Chromogranin and synaptophysin stains were negative, consistent with the previous diagnosis of an adenocarcinoma. Although the tumor shows clear evidence of gland formation, the mucin stain was negative, which is occasionally seen in more poorly differentiated adenocarcinomas.

These results do NOT change the previously rendered diagnosis of a moderately to poorly differentiated adenocarcinoma.

FINAL DIAGNOSIS:

SUMMARY STATEMENT

This lobectomy specimen from "left upper lobe of lung" demonstrates a moderate to poorly differentiated adenocarcinoma (3.3 cm.). The tumor has neuroendocrine features. The bronchial, vascular and pleural margins are free of tumor. Six lymph nodes identified are negative for metastatic carcinoma. The TNM stage of this lesion is T2; M0; MX.

LUNG, LEFT UPPER LOBE, THORACOTOMY AND LEFT UPPER LOBECTOMY –

- A. INVASIVE MODERATELY TO POORLY DIFFERENTIATED ADENOCARCINOMA (3.3 CM.).
- B. THE BRONCHIAL, VASCULAR, AND PLEURAL MARGINS OF RESECTION ARE FREE OF TUMOR.
- C. AREAS OF TUMOR SUGGEST POSSIBLE NEUROENDOCRINE DIFFERENTIATION. SPECIAL STAINS HAVE BEEN ORDERED AND THE RESULTS OF THESE STAINS WILL FOLLOW IN AN ADDENDUM.
- D. TWO INTRAPARENCHYMAL LYMPH NODES (0/2), NEGATIVE FOR MALIGNANCY.
- E. FOUR HILAR LYMPH NODES (0/4), NEGATIVE FOR MALIGNANCY.
- F. SURROUNDING LUNG SHOWS CHANGES OF EMPHYSEMA.
- G. TNM STAGE: T2; N0, MX.

[page 2 of 2]
SYNOPTIC - PRIMARY LUNG TUMORS

- A. Location: 5
1. RUL
2. RML
3. RLL*
4. LLL
5. LUL
6. Bronchus intermedius
- B. Procedure: 2
1. Wedge/Segmental
2. Lobectomy
3. Bilobectomy
4. Pneumonectomy
- C. Size of tumor (maximum dimension): 3.3 cm.
- D. Satellite nodules: 2
1. yes
2. no
- E. Type: 3
1. Invasive squamous carcinoma
2. Basaloid squamous carcinoma
3. Invasive adenocarcinoma
4. Bronchioloalveolar carcinoma, nonmucinous type
5. Bronchioloalveolar carcinoma, mucinous type
6. Large cell carcinoma
7. Clear cell carcinoma
8. Giant cell carcinoma
9. Sarcomatoid carcinoma
10. Blastoma
11. Fetal type adenocarcinoma
12. Small cell carcinoma
13. Carcinoid
14. Atypical carcinoid
15. Sarcoma
16. Adenosquamous carcinoma
17. Mixed non-small cell carcinoma, NOS
18. Carcinosarcoma
19. Other
- F. Architectural grade: 2
1. well
2. moderate
3. poor/undifferentiated
- G. Nuclear grade: 3
1. Low
2. Intermediate
3. High
- H. Central vs. peripheral origin: 1
1. yes
2. no
- I. Visceral pleural invasion through elastica: 2
1. yes
2. no
- J. Parietal pleural invasion: 2
1. yes
2. no
- K. Chest wall invasion (into skeletal muscle or soft tissue): 2
1. yes
2. no
- L. Angiolymphatic invasion: 2
1. yes
2. no
- M. Necrosis: 1
1. ≤50%
2. >50%
- N. Surgical margins involved: 2
1. yes
2. no
- O. Inflammatory (desmoplastic) reaction: 2
1. mild
2. moderate
3. severe
- P. Hilar lymph node involvement: 2
1. yes
2. no
- Q. If hilar lymph nodes involved, N/A positive / # examined = # / #
- R. Mediastinal nodes involved: N/A
1. yes
2. no
3. not applicable
- S. Mediastinal node group(s) involved: N/A / # / # / # / # / #
1. Level 4R
2. Level 5R
3. Level 6R
4. Level 7R
5. Level 9R
6. Level 10R
7. Level 4L
8. Level 5L
9. Level 6L
10. Level 7L
11. Level 9L
12. Level 10L
- T. Underlying disease(s): 1 / # / # / #
1. Emphysema
2. Bronchiectasis
3. Tumorlets
4. Smokers bronchiolitis
5. Asthma
6. Parenchymal scar
7. Pneumoconiosis, NOS
8. Chronic interstitial pneumonia
- U. TNM Stage: T 2 N 0 M X

Source: NCI Genomic Data Commons file 484f1f20-438c-4aba-b91b-a49ca60b6a3d (TCGA-50-5931.396C0F5F-1B86-4AA9-88EF-CA9220F4CCF3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).